Somatic mutation profile of tumor specimen TCGA-LK-A4O0-01A (aliquot TCGA-LK-A4O0-01A-11D-A34C-32) from TCGA case TCGA-LK-A4O0, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.6 years (29,798 days).
Specimen TCGA-LK-A4O0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6e4a9aa-acff-44f6-8c36-040ebbf312bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4O0-10A (Blood Derived Normal), aliquot TCGA-LK-A4O0-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af96b578-0416-4d3e-b2fa-9c45f3d1b094

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Nonsense Mutation 2, Splice Region 1, Intron 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH8 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV54848976, COSV54860835; called by muse, mutect2, varscan2
- CFHR5 | c.1160A>C p.Q387P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56825892; called by muse, mutect2, varscan2
- FHOD3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV99940746; called by muse, mutect2, varscan2
- HOOK2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs184223914; called by muse, mutect2, varscan2
- KIF21B | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.206); catalogued as rs751378411; called by muse, mutect2, varscan2
- NRTN | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1469187528; called by muse, mutect2, varscan2
- ZNF761 | c.1637G>C p.G546A | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs376647746; called by muse, mutect2, varscan2
- AMELY | c.332G>T p.R111L (on ENST00000383036 / NM_001364814.1; = p.R97L on NM_001143.1) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ATP6V1G1 | c.287T>G p.L96W | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BCAN | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP10 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP58 | c.740A>C p.Q247P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- EHHADH | c.258T>A p.N86K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ELAPOR2 | c.2064C>A p.D688E (on ENST00000450689 / NM_001142749.3; = p.D521E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- GALNT11 | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2
- GPX8 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- HINFP | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYAL3 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFT172 | c.2954G>A p.G985D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- INTS13 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- KL | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- LATS2 | c.2089A>T p.K697* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- MOCOS | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NCKAP1L | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- RNF2 | c.-2C>T | Splice Region (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- SFTPA2 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- TAF11 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by mutect2, varscan2
- AKAP3 | c.951A>T p.L317= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- C10orf71 | c.465C>T p.S155= | Silent (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- CASKIN2 | c.2178C>T p.P726= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs201582349; called by muse, mutect2, varscan2
- COL17A1 | c.4272G>A p.A1424= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs762902414, COSV59827950; called by muse, mutect2, varscan2
- GABRR1 | c.381C>T p.Y127= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
- KLHL7 | c.1233C>T p.H411= (on ENST00000339077 / NM_001031710.3; = p.H363= on NM_018846.5) | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- MFSD13A | c.330G>A p.A110= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs745623388, COSV53268290; called by muse, mutect2
- NASP | c.1839C>G p.V613= | Silent (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- PIH1D2 | c.63T>C p.D21= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- TGIF2LY | c.414C>A p.T138= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs1198521244; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505653 C>T | 5'Flank (SNP) | VAF 36/175 reads (21%) | catalogued as rs776606162; called by muse, mutect2, varscan2
- IGLL3P | n.250C>G | RNA (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- TENM2 | c.503-120850G>A | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
